Somatic mutation profile of tumor specimen TCGA-MQ-A4LP-01A (aliquot TCGA-MQ-A4LP-01A-11D-A34C-32) from TCGA case TCGA-MQ-A4LP, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 67.5 years (24,652 days).
Specimen TCGA-MQ-A4LP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb0a4f2e-27ca-42ce-90f6-2e328fbf2a2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MQ-A4LP-10B (Blood Derived Normal), aliquot TCGA-MQ-A4LP-10B-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b80b568-bcda-40b3-9f6f-c4a02cfb350f

The open-access MAF lists 51 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Nonsense Mutation 3, Frame Shift Del 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL7B | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs775693299; called by muse, mutect2, varscan2
- HTR2C | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52210428; called by muse, mutect2, varscan2
- KCNU1 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 76/204 reads (37%) | catalogued as rs567477009, COSV67757795; called by muse, mutect2, varscan2
- MTHFSD | c.1075G>A p.V359I (on ENST00000360900 / NM_001159377.2; = p.V358I on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as rs780483834, COSV100530619; called by muse, mutect2, varscan2
- NCOA6 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100750330; called by muse, mutect2, varscan2
- NOXO1 | c.727T>A p.C243S (on ENST00000397280 / NM_172168.3; = p.C237S on NM_144603.4) | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.532); catalogued as rs749378489; called by muse, mutect2, varscan2
- ORM2 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1216844636; called by muse, mutect2, varscan2
- PRDM1 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs955184509, COSV64847622; called by muse, mutect2, varscan2
- SLC26A5 | c.1177A>G p.I393V | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.233); catalogued as rs555983287; called by muse, mutect2, varscan2
- SPATC1 | c.790dup p.Q264Pfs*107 | Frame Shift Ins (INS) | VAF 46/226 reads (20%) | catalogued as rs782200741; called by mutect2, varscan2
- ST6GALNAC1 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 26/83 reads (31%) | PolyPhen probably damaging (1); catalogued as rs141702482; called by mutect2, varscan2
- SYT10 | c.383A>C p.E128A | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as COSV57345398; called by muse, mutect2, varscan2
- ZNF740 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57239942; called by muse, mutect2, varscan2
- ADD2 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARMC10 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- AXDND1 | c.1394A>T p.K465I | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- BRSK1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLUD2 | c.1364C>G p.T455S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- JAZF1 | c.544A>T p.K182* | Nonsense Mutation (SNP) | VAF 32/116 reads (28%) | called by muse, mutect2, varscan2
- KIF26A | c.4238C>G p.P1413R | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- KLC1 | c.956T>C p.L319S | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KMT2E | c.3548G>C p.S1183T | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LHFPL6 | c.280G>C p.G94R | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LRR1 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LRRN4 | c.263G>C p.R88P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MMP24 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2
- NCOR1 | c.5936C>T p.A1979V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- NEO1 | c.3084C>G p.Y1028* | Nonsense Mutation (SNP) | VAF 51/116 reads (44%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.128T>G p.I43R | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- PRPF8 | c.968T>G p.L323R | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- PWWP3B | c.1323A>C p.R441S | Missense Mutation (SNP) | VAF 52/68 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RETREG1 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 103/158 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUCLA2 | c.650A>G p.E217G | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); called by muse, mutect2
- TLE4 | c.1058T>C p.V353A | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- TXNIP | c.205T>C p.Y69H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VPS13B | c.6771del p.L2258Yfs*59 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel
- YWHAQ | c.56A>G p.Y19C | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ZNF492 | c.1350A>T p.K450N | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ENTPD2 | c.924C>T p.H308= | Silent (SNP) | VAF 52/122 reads (43%) | called by muse, mutect2, varscan2
- FER1L5 | c.4041C>T p.F1347= (on ENST00000623019; = p.F1320= on NM_001293083.2) | Silent (SNP) | VAF 53/149 reads (36%) | catalogued as rs760313932, COSV67606580; called by muse, mutect2, varscan2
- LAMA3 | c.1659A>G p.G553= | Silent (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- MYBPC1 | c.1524C>T p.Y508= (on ENST00000550270 / NM_206820.2; = p.Y533= on NM_002465.4) | Silent (SNP) | VAF 58/150 reads (39%) | called by muse, mutect2, varscan2
- PBX2 | c.27C>T p.P9= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs751878703; called by muse, mutect2
- REP15 | c.69G>T p.V23= | Silent (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- SULT1C4 | c.504T>G p.T168= | Silent (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- SYNE1 | c.14749C>T p.L4917= (on ENST00000367255 / NM_182961.4; = p.L4846= on NM_033071.3) | Silent (SNP) | VAF 63/85 reads (74%) | called by muse, mutect2, varscan2
- SYT9 | c.57C>T p.L19= | Silent (SNP) | VAF 35/44 reads (80%) | catalogued as rs983164962; called by muse, mutect2, varscan2
- TEX13A | c.1062T>C p.H354= | Silent (SNP) | VAF 39/46 reads (85%) | catalogued as COSV61161315; called by muse, mutect2, varscan2
- TRIO | c.681C>T p.A227= | Silent (SNP) | VAF 48/284 reads (17%) | catalogued as rs1191892319; called by muse, mutect2, varscan2
- ZNF594 | c.66A>G p.E22= | Silent (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- AL031659.1 | chr20:37168202 A>G | 5'Flank (SNP) | VAF 41/101 reads (41%) | called by muse, mutect2, varscan2
